Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JY-01A (Primary Tumor).

[page 1 of 4]
M

(174.0cm 74.8kg BSA: 1.9m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT NECK DISSECTION, LEVEL 2A:

Twelve lymph nodes, negative for tumor (0/12).

(B) LEFT NECK DISSECTION, LEVEL 2B:

Fibroadipose tissue without lymphoid tissue, negative for tumor.

(C) LEFT NECK DISSECTION, LEVEL 3:

Seven lymph nodes, negative for tumor(0/7).

(D) LEFT NECK DISSECTION, LEVEL 4:

Eight lymph nodes, negative for tumor(0/8).

(E) LATERAL DEEP MARGIN:

Fibroadipose tissue and skeletal muscle, negative for tumor.

(F) MASSETER MARGIN:

Skeletal muscle, negative for tumor.

(G) ANTERIOR SUBLINGUAL MARGIN:

Fibroadipose tissue and minor salivary gland, negative for tumor.

(H) ANTERIOR ALVEOLAR NERVE:

Nerve, negative for tumor.

(I) RETROMOLAR TRIGONE, DEEP MARGIN:

Squamous mucosa with lymphoid stroma, negative for tumor.

(J) POSTERIOR BUCCAL MARGIN:

Ulcerated mucosa with fordyce granules , negative for tumor.

(K) POSTERIOR FLOOR OF MOUTH, MARGIN:

Squamous mucosa, negative for tumor.

(L) COMPOSITE RESECTION LEFT MANDIBLE, BUCCAL, FOM:
INVASIVE SQUAMOUS CARCINOMA -- Well differentiated

Tumor Features:

Gross: Exophytic

Size: 5.0 cm in largest dimension

Invasion: Present, depth at least 1.5 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: final evaluation pending decalcification sections.

Vascular Invasion: Absent

Bone / Cartilage Invasion: Pending Decalcification (see addendum)

Three lymph nodes, negative for tumor (0/3)

(M) TEETH:

Teeth, gross only.

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

C64F

Site Oral cavity NOS
path C06.9

Buccal mucosa
C06.0

8/9/13

[page 2 of 4]
Accession:

(174.0cm 74.9kg BSA: 1.9m²)

Specimen Date/Time:

GROSS DESCRIPTION

- (A) LEFT NECK DISSECTION, LEVEL 2A – Received is a 4.0 x 2.2 x 1.0 cm fragment of fibroadipose tissue from which 14 possible lymph nodes are identified, ranging in size from 0.3 to 1.2 cm.
SECTION CODE: A1, five possible lymph nodes; A2, five possible lymph nodes; A3, four lymph nodes.
- (B) LEFT NECK DISSECTION, LEVEL 2B – Received is a 3.0 x 1.5 x 0.3 cm fragment of fibroadipose tissue from in which no definite lymph nodes are identified.
SECTION CODE: B1, B2, tissue, entirely submitted.
- (C) LEFT NECK DISSECTION, LEVEL 3 – Received is a 3.3 x 3.3 x 1.0 cm fragment of adipose tissue from which seven possible lymph nodes are identified ranging in size from 0.5 to 1.3 cm.
SECTION CODE: C1, one lymph node; C2, five possible lymph nodes; C3, one lymph node.
- (D) LEFT NECK DISSECTION, LEVEL 4 – Received is a 4.0 x 2.8 x 0.8 cm fragment of adipose tissue from which eight possible lymph nodes are identified, ranging in size from 0.3 to 2.0 cm.
SECTION CODE: D1, one lymph node, bisected; D2, four possible lymph nodes; D3, three lymph nodes.
- (E) LATERAL DEEP MARGIN, TRUE MARGIN INKED, STITCH ANTERIOR – Received is a 2.9 x 1.2 x 0.3 cm fragment of fibroadipose tissue with ink on one side and a stitch marking anterior aspect. The true margin is inked black and the anterior aspect is inked yellow, posterior aspect is inked green and the specimen is serially sectioned and entirely submitted in E1 and E2 for frozen section evaluation.
INK CODE: True margin – blue, anterior – yellow, posterior – green.
*FS/DX: MARGIN NEGATIVE FOR CARCINOMA.
- (F) MASSETER MARGIN – Received is a fragment of muscle tissue measuring 1.3 x 1.1 x 0.5 cm, with cattery on one side.
SECTION CODE: F1, entirely submitted for frozen section evaluation.
*FS/DX: NEGATIVE FOR CARCINOMA.
- (G) ANTERIOR SUBLINGUAL MARGIN – Received is a fragment of fibroadipose tissue measuring (0.9 x 0.6 x 0.3 cm). Submitted entirely for frozen section in G1.
*FS/DX: NEGATIVE FOR CARCINOMA.
- (H) ANTERIOR ALVEOLAR NERVE – Received are two fragments of pale-pink glistening firm tissue measuring 1.0 x 0.5 x 0.3 cm in aggregate. Entirely submitted for frozen section evaluation in H1.
*FS/DX: NEGATIVE FOR CARCINOMA.
- (I) RETROMOLAR TRIGONE, DEEP MARGIN, TRUE MARGIN INKED – A fragment of mucosa (1.4 x 0.6 x 0.6 cm). One surface shows smooth glistening mucosa with a faint surgeon's ink. The mucosa is reinked black and the specimen is submitted entirely for frozen section examination in block I1.
*FS/DX: NEGATIVE FOR CARCINOMA.
- (J) POSTERIOR BUCCAL MARGIN, INK AT TRUE MARGIN – A segment of mucosa (1.2 x 0.3 x 0.3 cm). One surface of the mucosa shows stained surgeon's ink. The specimen is submitted entirely for frozen section examination in block J1.
*FS/DX: NEGATIVE FOR CARCINOMA.
- (K) POSTERIOR FLOOR OF MOUTH MARGIN, TRUE MARGIN INKED – A fragment of mucosa (1.6 x 0.3 x 0.3 cm). One surface of the mucosa bears faint surgeon's ink that is reinked black and submitted entirely for frozen in K1.
*FS/DX: NEGATIVE FOR CARCINOMA.
- (L) COMPOSITE RESECTION LEFT MANDIBLE, BUCCAL, FOM – A composite resection consists of a segment of mandible, portion of buccal mucosa and portion of the floor of mouth, overall 9.5 x 4 x 4 cm. An ulcerated lesion (2.8 x 2.5 x 1.5 cm) is in the floor of mouth however corresponds to a larger lesion extending to involve the gingival and buccal surface (~5.0 cm maximum dimension). The surface of the mandible appears eroded. The lesion is about 0.5 cm to the closest soft tissue margin. Multiple lymph nodes are identified. Soft tissue is entirely submitted in L1 – L10. The mandible is submitted to bone lab for further processing. Both tumor and normal tissue were submitted to tissue bank.
- (M) TEETH, GROSS ONLY – Multiple pale-gray teeth (7.0 x 1.5 x 1.2 cm in aggregate). Gross ID only.

CLINICAL HISTORY

SNOMED CODES

T-51200, M-80703

Some tests reported here may have been developed and performance characteristics determined by

These tests have not been

[page 3 of 4]
Page: 3

M

(174.0cm 74.3kg BSA: 1.9m²)

Accession:

Specimen Date/Time:

specifically cleared or approved by the U.S. Food and Drug Administration *

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 4 of 4]
Accession:
Specimen Date/Time:

M

(174.6cm 74.9kg BSA: 1.9m²)

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(L) COMPOSITE RESECTION LEFT MANDIBLE, BUCCAL AND FOM

SQUAMOUS CARCINOMA, involving bone.

Anterior mandible margin, en face: Negative for tumor

GROSS DESCRIPTION

(L) COMPOSITE RESECTION LEFT MANDIBLE, BUCCAL AND FOM – The bone is serially sectioned and lesion extends to a depth of 0.7 cm and grossly abutts the nerve. The mandible margin is grossly uninvolved.

SECTION CODE: L11, anterior mandible margin, bisected and en face; L12, L13, representatives of lesion involving bone and nerve. L11-L13 submitted after decalcification.
Entire report and diagnosis completed by:

-----END OF REPORT-----

Prior Maintenance History		☒

Source: NCI Genomic Data Commons file 3dc3b5ec-7b7b-48ba-af77-805206c2ce34 (TCGA-CV-A6JY.67367B8C-C268-4F86-903D-D5D1C4DA03CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).